FM case AD3631 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Penis.
https://portal.gdc.cancer.gov/cases/ef7473b6-e8d0-4f42-8286-46cb29790527

Male, 46.6 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the penis; metastasis biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
